Surgical pathology report (de-identified scan), TCGA case TCGA-OX-A56R, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of North Carolina, specimen TCGA-OX-A56R-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

ICD-O-3

Glioblastoma, NOS

9440/3

Site:

Brain (R) temporal

C71.2

Op 12/5/12

Diagnosis:

A, B: Brain, right temporal, excision

- Glioblastoma, WHO grade IV (see comment)

Comment:

The neoplasm shows areas with divergent differentiation. In some areas, the neoplastic cells have features of gemistocytes or fibrillary astrocytes. In other areas, the neoplastic cells are small cells with little cytoplasm and raise the possibility of a small-cell component or a PNET-like component.

, MD, PhD, and, MD, PhD, also reviewed this case and concur that this is a glioblastoma with areas of divergent differentiation.

Sections of this tumor were submitted to the for MGMT testing. The results of this testing will be reported in a separate report by the

Intraoperative Consult Diagnosis:

A frozen section consultation was requested

FSA1: Brain, right temporal lobe mass, biopsy
- Glioblastoma. Dr. concurs.

Drs. on at .

Frozen Section Pathologist:

Clinical History:

with right temporal-lobe brain mass.

Gross Description:

Received are two appropriately labeled containers.

[page 2 of 3]
Container A is received fresh for frozen section, which holds multiple tan/pink soft tissue fragments, 1.5 x 1.0 x 0.8 cm in aggregate. Representative sections are submitted in block FSA1 and remnant tissue in A2,

Container B holds an irregular piece of red/tan soft tissue measuring 2.2 x 1.4 x 1.0 cm. The specimen is entirely submitted in blocks B1 and B2, . Tissue was submitted to Tissue Procurement facility.

Sections from specimens A and B show a high-grade astrocytoma with nuclear pleomorphism, mitotic figures, microvascular proliferation, and necrosis. The neoplasm shows areas with divergent differentiation. In some areas, the neoplastic cells have features of gemistocytes or fibrillary astrocytes. In other areas, the neoplastic cells are small cells with little cytoplasm and raise the possibility of a small-cell component or a PNET-like component. Immunostained sections of the neoplasm show diffuse staining of the neoplastic cells for GFAP and CD56. The vimentin immunostain shows positivity within both the larger-cell component and within the smaller-cell component. Areas of the neoplasm also immunostain positively for synaptophysin. The Ki-67 immunostain shows areas within the neoplasm that have a high labeling index. Controls immunostain appropriately. The histologic and immunohistochemical features are consistent with a glioblastoma, WHO grade IV.

For cases in which immunostains are performed, the following applies:
Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this

[page 3 of 3]
case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by the Anatomic Pathology Department. These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Procedures/Addenda:
Addendum

Addendum

The purpose of this addendum is to report the results of outside studies for PTEN immunohistochemistry.

Addendum Comment

Material was sent to for PTEN immunohistochemistry. Outside report from gives the following result:

PTEN IHC results: negative

The original diagnoses are unchanged.

Critera	Yes	No

Source: NCI Genomic Data Commons file a28571b8-5ab6-4cfb-9159-fc86537ff8be (TCGA-OX-A56R.9EF7E637-46F9-4498-B41C-D1219D20636A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).